Somatic mutation profile of tumor specimen TCGA-AN-A0XV-01A (aliquot TCGA-AN-A0XV-01A-11D-A10G-09) from TCGA case TCGA-AN-A0XV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.8 years (24,779 days).
Specimen TCGA-AN-A0XV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08b4b364-a3a1-4585-be47-8269f2757fe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0XV-10A (Blood Derived Normal), aliquot TCGA-AN-A0XV-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cc836b4-4199-41b8-820b-cef1db908044

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 20, Silent 8, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC126283.2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 6/172 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV101144796; called by muse, mutect2
- ANKRD16 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as rs774142230, COSV51947360; called by muse, mutect2
- CDK2AP1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1271472566, COSV55542333; called by muse, mutect2
- CEP120 | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 74/261 reads (28%) | catalogued as rs777687497, COSV60265385; called by muse, mutect2, varscan2
- COL25A1 | c.1895T>C p.L632P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV101211701; called by muse, mutect2
- CPNE3 | c.820-2A>C p.X274_splice | Splice Site (SNP) | VAF 121/1075 reads (11%) | catalogued as COSV99548192; called by muse, mutect2, varscan2
- CYP26B1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1448467960, COSV50010722; called by muse, mutect2, varscan2
- DHX15 | c.1495T>A p.Y499N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61026796; called by muse, mutect2, varscan2
- FASTKD3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV52942245; called by muse, mutect2, varscan2
- FASTKD5 | c.2053T>G p.C685G | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53905863; called by muse, mutect2, varscan2
- FGD5 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs749345174, COSV53242031; called by muse, mutect2, varscan2
- GMDS | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66433625; called by muse, mutect2, varscan2
- HACE1 | c.2069A>T p.N690I | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53502043; called by muse, mutect2, varscan2
- ITFG1 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57748256; called by muse, mutect2, varscan2
- KMT2C | c.2045C>G p.S682* | Nonsense Mutation (SNP) | VAF 49/159 reads (31%) | catalogued as COSV51435734; called by muse, mutect2, varscan2
- LACTB | c.721A>T p.M241L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV99979100; called by muse, mutect2
- MLEC | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57329576; called by muse, mutect2, varscan2
- MROH2B | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68183599; called by muse, mutect2, varscan2
- MYO10 | c.2906G>C p.S969T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99946479; called by muse, mutect2
- NCAM2 | c.1294del p.I432Ffs*8 | Frame Shift Del (DEL) | VAF 36/161 reads (22%) | catalogued as COSV53082481; called by mutect2, pindel, varscan2
- NEK5 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62879763; called by muse, mutect2, varscan2
- OR2B3 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV65850900, COSV65851044; called by muse, mutect2, varscan2
- PATJ | c.1645_1646del p.Q549Dfs*4 | Frame Shift Del (DEL) | VAF 100/400 reads (25%) | catalogued as rs757445412; called by pindel, varscan2
- PSMD1 | c.124del p.V42* | Frame Shift Del (DEL) | VAF 20/169 reads (12%) | catalogued as COSV58078450, COSV58083546; called by mutect2, pindel, varscan2
- RAB3GAP2 | c.2945T>C p.V982A | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1167541927, COSV62783685; called by muse, mutect2, varscan2
- RAD54L | c.2124C>A p.H708Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58439948; called by muse, mutect2, varscan2
- UHRF1 | c.2173A>G p.I725V (on ENST00000612630 / NM_001290050.1; = p.I738V on NM_013282.4) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.085); catalogued as COSV53574453; called by muse, mutect2, varscan2
- ZMYM3 | c.659_662del p.S220Cfs*6 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by pindel, varscan2
- ASH1L | c.4455C>T p.H1485= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as rs1382788417, COSV100853623; called by muse, mutect2
- DOCK11 | c.5100A>G p.E1700= | Silent (SNP) | VAF 11/241 reads (5%) | catalogued as COSV99354967; called by muse, mutect2
- GNAO1 | c.897C>T p.D299= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs148878451; ClinVar: likely benign; called by muse, mutect2, varscan2
- IL17RD | c.654C>T p.F218= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs554074599, COSV56337695; called by muse, mutect2, varscan2
- NFE2L3 | c.966T>C p.C322= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs745490757, COSV50227685; called by muse, mutect2, varscan2
- SLC5A7 | c.24G>C p.L8= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV50891226; called by muse, mutect2, varscan2
- TENM2 | c.1935C>T p.C645= (on ENST00000518659 / NM_001122679.2; = p.C413= on NM_001080428.3) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs755299086, COSV69128984, COSV69140214; called by muse, mutect2
- VPS13B | c.4893G>A p.L1631= | Silent (SNP) | VAF 18/412 reads (4%) | catalogued as COSV100663915; called by muse, mutect2
